Gene-level copy-number profile of tumor specimen ALCH-B2MB-TTP1-A from ALCHEMIST case ALCH-B2MB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.9 years (23,325 days).
Specimen ALCH-B2MB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59befae4-ffbd-41f3-bab5-7fc78289de2f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/873c403e-8989-451b-9c12-327967594fe2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 137; copy number 2: 23,598; copy number 3: 10,450; copy number 4: 19,118; copy number 5: 3,603; copy number 6: 578; copy number 7: 64; copy number 8: 514; copy number 9: 27; copy number 10: 249; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:112,589,040–112,614,431, 2 genes (within-gene range 0–3): AC012442.2, AC012442.1.
- chr2:132,523,617–132,523,936, 1 gene (within-gene range 0–3): RN7SKP103.
- chr5:179,678,560–179,806,952, 7 genes (within-gene range 0–2): CBY3, CANX, HMGB3P22, MAML1, LTC4S, MGAT4B, MIR1229.
- chr9:8,936,079–8,963,077, 1 gene (within-gene range 0–3): AL596451.1.
- chr10:43,323,665–43,350,792, 3 genes: LINC02633, AC068707.1, RNU6ATAC11P.
- chr10:87,659,613–87,863,533, 5 genes (within-gene range 0–2): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene (within-gene range 0–2): AC063965.2.
- chr16:46,469,341–46,569,097, 2 genes: ANKRD26P1, RNU6-845P.
- chr16:66,908,122–66,934,423, 3 genes: CDH16, RRAD, CIAO2B.
- chr21:14,075,950–14,076,038, 1 gene (within-gene range 0–2): AP001347.2.
- chr21:23,857,081–24,547,942, 8 genes: AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,037 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–3,736,201, 196 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:51,577,179–51,878,937, 9 genes, copy number 6 (within-gene range 4–6): OSBPL9, GAPDHP51, SLC25A6P3, AL050343.1, NRDC, AL050343.2, AL050343.3, MIR761, TSEN15P2.
- chr1:148,263,476–148,436,926, 17 genes, copy number 5: RNVU1-22, LINC01731, AC245100.3, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2.
- chr1:148,772,640–149,048,286, 5 genes, copy number 5–20 (within-gene range 2–20): SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P.
- chr1:234,356,704–235,328,219, 32 genes, copy number 5 (within-gene range 4–5): AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753.
- chr2:9,740,643–13,331,683, 77 genes, copy number 5–7 (broad region; genes not listed).
- chr2:36,299,388–54,671,446, 283 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:54,972,187–62,662,829, 121 genes, copy number 5 (broad region; genes not listed).
- chr2:63,119,559–63,827,843, 2 genes, copy number 6 (within-gene range 2–6): WDPCP, Metazoa_SRP.
- chr2:63,517,892–64,751,005, 32 genes, copy number 6–7: AC016734.1, MDH1, PRELID1P6, RPS4XP5, RPL27P6, CSP1, HNRNPA1P66, UGP2, AC114748.1, VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9.
- chr2:84,423,528–86,778,041, 72 genes, copy number 5 (broad region; genes not listed).
- chr2:91,617,160–92,035,000, 18 genes, copy number 8 (within-gene range 3–8): LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P, IGKV1OR2-1, ABCD1P5, AC127391.1, PABPC1P6, SLC9B1P2, ACTR3BP2, CHEK2P3, AC128677.1, IGKV1OR2-2.
- chr2:231,056,845–231,173,116, 3 genes, copy number 6: PSMD1, HTR2B, RNU1-93P.
- chr3:134,385,197–134,575,017, 6 genes, copy number 5: HMGN1P9, HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1.
- chr3:162,486,541–186,110,318, 360 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:187,932,764–197,888,436, 207 genes, copy number 5–6 (broad region; genes not listed).
- chr4:49,096–8,871,839, 215 genes, copy number 5 (broad region; genes not listed).
- chr4:10,143,367–16,898,678, 81 genes, copy number 5 (broad region; genes not listed).
- chr4:64,275,257–91,601,913, 451 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr6:2,832,332–17,987,635, 264 genes, copy number 9–10 (broad region; genes not listed).
- chr6:105,612,667–106,668,417, 19 genes, copy number 5: LINC02836, Z97206.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65.
- chr7:37,032–2,844,308, 74 genes, copy number 5 (broad region; genes not listed).
- chr7:74,843,754–75,416,787, 28 genes, copy number 5 (within-gene range 4–5): STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1.
- chr8:31,639,222–38,468,834, 110 genes, copy number 5–7 (broad region; genes not listed).
- chr8:67,849,044–69,860,540, 25 genes, copy number 5: NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2.
- chr8:140,636,281–141,002,216, 4 genes, copy number 7 (within-gene range 4–7): ERICD, PTK2, MIR151A, AC105235.1.
- chr9:39,748,514–40,153,147, 13 genes, copy number 5: GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:125,567,579–125,967,377, 4 genes, copy number 5: AL162584.1, HNRNPA1P15, AL358074.1, PBX3.
- chr10:14,061–4,848,062, 68 genes, copy number 6–9 (broad region; genes not listed).
- chr12:12,310–12,568,776, 448 genes, copy number 5 (broad region; genes not listed).
- chr12:131,828,393–132,687,376, 42 genes, copy number 5: MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3, EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5, AC138466.2, DDX51, NOC4L, AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE.
- chr15:32,615,144–35,546,193, 71 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:85,191,438–85,750,281, 16 genes, copy number 5: CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2.
- chr15:89,504,909–101,850,324, 295 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–3,149,963, 300 genes, copy number 5 (broad region; genes not listed).
- chr18:35,581,117–36,180,557, 13 genes, copy number 6 (within-gene range 3–6): GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2.
- chr18:51,845,007–64,019,779, 182 genes, copy number 5–8 (broad region; genes not listed).
- chr18:75,696,044–79,002,677, 59 genes, copy number 5–6: LINC01898, AC021506.1, AC021506.2, AC090457.1, AC011095.1, AC103808.6, LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5, ZNF516, AC009716.1, AC009716.2, AC018413.1, ZNF516-DT, LINC00683, AC034110.1, LINC01927, LINC01879, ARL2BPP1, CCND3P2, AC139085.1, ZNF236-DT, RNU6-346P, AC027575.2, ZNF236, RPL26P35, Metazoa_SRP, AC027575.1, AC093330.1, MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2, AC100863.1, GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3.
- chr20:61,953,469–64,079,988, 126 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
